Somatic mutation profile of tumor specimen TCGA-14-1043-01B (aliquot TCGA-14-1043-01B-11D-1845-08) from TCGA case TCGA-14-1043, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 61.3 years (22,392 days).
Specimen TCGA-14-1043-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 58aef770-086c-4d46-a4d8-3ee9e928a283.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-14-1043-10A (Blood Derived Normal), aliquot TCGA-14-1043-10A-01D-1845-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ef04461d-ec6b-45f4-af97-311f5a0f782e

The open-access MAF lists 25 somatic variants for this specimen: 17 protein-altering or splice-affecting, 7 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 7, Frame Shift Del 2, Nonsense Mutation 2, Intron 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NF1 | c.5902C>T p.R1968* (on ENST00000358273 / NM_001042492.3; = p.R1947* on NM_000267.3) | Nonsense Mutation (SNP) | VAF 19/67 reads (28%) | catalogued as rs137854552, CM900173, COSV62199973; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ARRDC3 | c.562T>G p.S188A | Missense Mutation (SNP) | VAF 51/220 reads (23%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.867); catalogued as COSV54365675; called by muse, mutect2, varscan2
- CAMKV | c.1400C>A p.P467Q | Missense Mutation (SNP) | VAF 29/96 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.015); catalogued as COSV56556235; called by muse, mutect2, varscan2
- CASP8AP2 | c.5071G>A p.V1691I | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.009); catalogued as rs1205834849, COSV52747935; called by muse, mutect2, varscan2
- COL12A1 | c.3091C>T p.R1031C | Missense Mutation (SNP) | VAF 21/97 reads (22%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.91); catalogued as rs575168916, COSV59396982; called by muse, mutect2, varscan2
- CUX2 | c.4279G>A p.A1427T | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); catalogued as rs746118929, COSV55634469; called by muse, mutect2, varscan2
- HOXB8 | c.47G>C p.G16A | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.991); catalogued as COSV53310872; called by muse, mutect2, varscan2
- HUNK | c.837C>A p.D279E | Missense Mutation (SNP) | VAF 27/120 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.212); catalogued as COSV54230152; called by muse, mutect2, varscan2
- JAKMIP2 | c.1760G>A p.R587Q | Missense Mutation (SNP) | VAF 59/232 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs866811241, COSV54607402; called by muse, mutect2, varscan2
- NF1 | c.3610del p.R1204Gfs*11 | Frame Shift Del (DEL) | VAF 21/101 reads (21%) | catalogued as CM000027, CM973234, COSV62201783; called by mutect2, pindel, varscan2
- OR5F1 | c.218A>C p.N73T | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV53547063; called by muse, mutect2, varscan2
- PCK1 | c.1700A>C p.K567T | Missense Mutation (SNP) | VAF 52/74 reads (70%) | SIFT tolerated (0.53); PolyPhen benign (0.005); catalogued as COSV60129075; called by muse, mutect2, varscan2
- PEX1 | c.590A>G p.K197R | Missense Mutation (SNP) | VAF 18/95 reads (19%) | SIFT tolerated (0.48); PolyPhen benign (0.015); catalogued as COSV50401777; called by muse, mutect2, varscan2
- RFX4 | c.207T>G p.Y69* | Nonsense Mutation (SNP) | VAF 23/97 reads (24%) | catalogued as COSV63505285; called by muse, mutect2, varscan2
- RICTOR | c.3564T>G p.N1188K | Missense Mutation (SNP) | VAF 63/243 reads (26%) | SIFT tolerated (0.58); PolyPhen benign (0.006); catalogued as COSV57124117; called by muse, mutect2, varscan2
- FAM83D | c.1406dup p.S470Ifs*32 | Frame Shift Ins (INS) | VAF 22/116 reads (19%) | called by mutect2, pindel, varscan2
- FXR1 | c.102_103del p.N34Kfs*11 | Frame Shift Del (DEL) | VAF 10/48 reads (21%) | called by mutect2, pindel, varscan2
- CEP350 | c.2277C>G p.L759= | Silent (SNP) | VAF 40/161 reads (25%) | catalogued as COSV62604446; called by muse, mutect2, varscan2
- CMSS1 | c.588G>A p.A196= | Silent (SNP) | VAF 19/92 reads (21%) | catalogued as rs750330461, COSV70436440; called by muse, mutect2, varscan2
- KIF12 | c.654C>T p.S218= (on ENST00000640217; = p.S80= on NM_138424.1) | Silent (SNP) | VAF 4/17 reads (24%) | catalogued as COSV65117527; called by muse, mutect2
- KRT3 | c.381G>A p.G127= | Silent (SNP) | VAF 5/14 reads (36%) | catalogued as rs117364830, COSV58814564; called by muse, varscan2
- NEIL1 | c.249C>T p.G83= | Silent (SNP) | VAF 21/63 reads (33%) | catalogued as COSV61833671; called by muse, mutect2, varscan2
- SV2C | c.216C>T p.D72= | Silent (SNP) | VAF 16/57 reads (28%) | catalogued as rs760204358, COSV59216333; called by muse, mutect2, varscan2
- ZNF653 | c.1773C>T p.C591= | Silent (SNP) | VAF 15/46 reads (33%) | catalogued as rs746767532, COSV53403528; called by muse, mutect2, varscan2
- RUSC1 | c.-86-340G>A | Intron (SNP) | VAF 10/25 reads (40%) | catalogued as COSV52740659; called by muse, mutect2, varscan2
